Gene-level copy-number profile of tumor specimen TCGA-2G-AAH7-01A from TCGA case TCGA-2G-AAH7, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 48.0 years (17,531 days).
Specimen TCGA-2G-AAH7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file da58abb6-841c-48f7-94d2-bf9dd2f3a3ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAH7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/dec36a7b-9505-48df-bc1d-b2332c69a3c7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 525; copy number 2: 12,077; copy number 3: 18,943; copy number 4: 17,960; copy number 5: 4,430; copy number 6: 1,716; copy number 7: 1,453; copy number 8: 831; copy number 9: 976.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,260 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:157,568,731–157,824,256, 1 gene, copy number 7 (within-gene range 2–7): AC093817.2.
- chr4:157,637,687–189,709,714, 388 genes, copy number 7 (broad region; genes not listed).
- chr7:37,032–112,521,670, 2,011 genes, copy number 7–9 (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 8 (within-gene range 7–8) (broad region; genes not listed).
- chr12:38,316,762–41,072,415, 29 genes, copy number 7: ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
